CCDI case PBBPIH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7480b4b7-58a6-4e3c-832b-5784daa056de

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 6.6 years (2,408 days).

Biospecimens (3 samples)
- Sample 0DEHN7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEHPR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEHPS: Tissue type: Tumor; Specimen type: Solid Tissue.
